Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IN, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IN-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. "Distal pancreas and spleen", resection:
Endocrine carcinoma of the pancreas, moderately-differentiated.
Tumor size : 5.0 x 5.0 x 3.0 cm.
Mitotic count: 7/10hpf.
Tumor necrosis: Absent.
Ki-67 index: up to 4%.
Histologic grade: Moderately-differentiated.
Angiolymphatic invasion: Present.
Peri-neural invasion: Present.
Surgical margins:
'New pancreatic margin' focally involved by the tumor.
Superior and inferior pancreatic margins free of tumor.
Spleen: No diagnostic histologic abnormality.
See comment.

COMMENT:

Mitotic figures in this neoplasm appear unusual, including elongated, pyknotic and popcorn-like forms, rendering precise mitotic evaluation challenging. Although this neoplasm is clinically localized at the time of surgical resection, based on the above findings, closer follow-up / evaluation for metastatic disease will be prudent.

Note:

This tumor was also reviewed by Dr. _____ who concurs with the above diagnosis.
The case was discussed with Dr. _____

- B. "New pancreatic margin", resection:
Endocrine carcinoma of the pancreas (3.0 X 1.5 X 1.0 cm), moderately differentiated, morphologically similar to tumor in specimen A.
Focally, the tumor involves the inked resection margin.
- C. "Superior pancreatic margin", resection:
Benign pancreatic tissue.
No tumor is identified.
- D. "Inferior pancreatic margin", resection:
Benign pancreatic tissue.
No tumor is identified.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by

Specimen(s) Received

- A Distal Pancreas and Spleen FS
B New Pancreatic Margin

ICD-O-3
Carcinoma, neuroendocrine NOS 8246/3
Site: ⁶⁶⁴ Pancreas body C25.1
⁶⁶⁴ Pancreas NOS C25.9
JW 4/16/14

[page 2 of 2]
- C Superior Pancreatic Margin
D Inferior Pancreatic Margin

Clinical History

NOT GIVEN.

PREOPERATIVE DIAGNOSIS: Pancreatic neuroendocrine tumor.

Frozen Section Diagnosis

- A. DISTAL PANCREAS AND SPLEEN, FROZEN SECTION:
A section closest to stapled margin is positive for carcinoma, with neuroendocrine features.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr. in

I, M.D., Ph.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh for OR consult, labeled "distal pancreas and spleen, frozen section". The specimen consists of a resected distal pancreas (6.5 x 4.5 x 3.5 cm), and adjacent spleen (9.0 x 6.5 x 3.5 cm), and adjacent adipose tissue and omentum (17.0 x 10.0 x 2.0 cm). The most distal margin of the spleen is stapled. The staples are removed and the closest adjacent underlying tissue, which reveals the pancreatic duct is submitted for frozen section as FSA1. The pancreatic duct is probe patent and grossly appears to be free of tumor. No normal pancreatic tissue is grossly appreciated. A section of the pancreas consists of a firm, gray-tan mass (..... cm), which grossly appears to extend to the margin of resection. Grossly, the mass does not extend to the adjacent spleen. The capsule of the spleen is intact, and the cut surface is grossly unremarkable. Sectioning of the adjacent adipose tissue isolates no definitive lymph nodes. A representative frozen section is taken and submitted as FSA1. Permanent sections are taken and submitted as:

- A2: Tumor showing its relationship to the pancreatic ducts and artery.
- A3: Tumor showing its relationship to surgical margin of resection.
- A4-A5: Additional sections of tumor.
- A6: Spleen showing relationship to capsule.
- A7: Additional section of spleen.
- A8-A10: Adipose tissue.

B. Specimen B is labeled "new pancreatic margin, long suture on margin for frozen section, no frozen section was performed as per Dr. . The specimen is received fresh and consists of a soft to moderately firm yellow-tan, irregular fragment of adipose tissue with palpable nodule (4.0 x 3.0 x 2.5 cm). The margin of resection is stapled. The staples are removed and the underlying tissue is marked with black ink. Serial sections reveal a firm, well-demarcated nodule (3.0 x 1.5 x 1.0 cm). The mass is at the surgical margin of resection. Representative sections are submitted as:

- B1: Mass showing its relationship to surgical margin of resection.
- B2-B3: Additional sections of mass.
- B4: Grossly unremarkable adipose tissue.

C. Specimen C is labeled "superior pancreatic margin". The specimen is received fresh and consists of a 0.5 x 0.5 x 0.3 cm, moderately firm yellow-tan irregular fragment of tissue, which is submitted in toto as C1.

D. Specimen D is labeled "inferior pancreatic margin". The specimen is received fresh and consists of a 0.5 x 0.5 x 0.2 cm, moderately firm yellow-tan irregular fragment of tissue, which is submitted in toto as D1.

Source: NCI Genomic Data Commons file 06daf364-1ec3-420b-951e-6b470ff775e8 (TCGA-3A-A9IN.6D70F2BD-C85B-4643-82A1-61AE8C541E63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).